Somatic mutation profile of tumor specimen 0DN83R from CCDI case PBCBFR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Follicular carcinoma, minimally invasive; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.5 years (5,285 days).
Specimen 0DN83R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f526568-9afc-427f-ae4a-9b43c3f8b906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN83M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a15a28df-f8ca-42d3-9558-473b43d8017f

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 2, Frame Shift Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5429A>T p.D1810V | Missense Mutation (SNP) | VAF 420/977 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615845, COSV58624974; called by muse, mutect2, varscan2
- OR2M2 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 434/1052 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62897936; called by muse, mutect2, varscan2
- OR4L1 | c.401C>A p.T134K | Missense Mutation (SNP) | VAF 57/525 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV59851444; called by muse, mutect2, varscan2
- BIRC6 | c.11303T>C p.L3768P | Missense Mutation (SNP) | VAF 28/1072 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); called by muse, mutect2
- CCDC17 | c.1166_1175del p.P389Lfs*26 | Frame Shift Del (DEL) | VAF 138/532 reads (26%) | called by mutect2, pindel, varscan2
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 24/962 reads (2%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 53/1795 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- ALCAM | c.18C>T p.A6= | Silent (SNP) | VAF 113/470 reads (24%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 70/1796 reads (4%) | called by muse, mutect2
- TLR4 | c.2331C>G p.T777= (on ENST00000355622 / NM_138554.5; = p.T737= on NM_003266.4) | Silent (SNP) | VAF 34/1118 reads (3%) | catalogued as COSV100842842, COSV62923583; called by muse, mutect2
- JAKMIP2 | c.2413-10073G>A | Intron (SNP) | VAF 90/1652 reads (5%) | catalogued as rs1439281459; called by muse, mutect2
- OBSL1 | c.-43_-42del | 5'UTR (DEL) | VAF 9/111 reads (8%) | catalogued as rs1491488448; ClinVar: uncertain significance; called by pindel, varscan2*
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 6/70 reads (9%) | catalogued as COSV55814242; called by muse, mutect2
- RHOA | c.*92A>G | 3'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
